Surgical pathology report (de-identified scan), TCGA case TCGA-59-2351, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-2351-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY HISTORY REPORT

CLINICAL HISTORY:

[REDACTED] with sl. mobile mass

FINAL DIAGNOSIS:

1. FS1 Left TUBE and OVARY, resection:
- SEROUS PAPILLARY CARCINOMA, poorly differentiated of left OVARY
- Size of tumor 18x15x9cm. (783gm.)
2. FS2 Right TUBE and OVARY, resection:
- SEROUS PAPILLARY CARCINOMA, poorly differentiated of right OVARY
- Size of tumor 13x8x5cm. (290gm.)
- Right fallopian tube, no specific pathologic changes, negative for tumor
3. UTERUS, resection:
- NODULAR METASTATIC SEROUS CARCINOMA to serosa of UTERUS
- EARLY SECRETORY ENDOMETRIUM
- ADENOMYOMA
- CHRONIC CERVICITIS with FOCAL SQUAMOUS METAPLASIA
4. Left pelvic LYMPH NODE: One (1) out of five (5) LYMPH NODES, POSITIVE FOR METASTATIC SEROUS CARCINOMA
5. Right pelvic LYMPH NODES: Three (3) lymph nodes, negative for tumor
6. SIGMOID nodule, biopsy: METASTATIC SEROUS CARCINOMA
7. Peri-aortic LYMPH NODES: Extensive METASTATIC SEROUS CARCINOMA to three (3) out of four (4) LYMPH NODES
8. OMENTUM, excision: Omental adipose tissue, negative for tumor
9. Tumor SIGMOID MESENTERIC: METASTATIC SEROUS CARCINOMA
10. OVARIAN tumor: SEROUS PAPILLARY CARCINOMA, poorly differentiated

[page 2 of 4]
DIAGNOSIS COMMENT:

NOTE: Verbal report to [REDACTED]

FROZEN SECTION DIAGNOSIS:

1. FS1 LT.TUBE & OVARY

Adenocarcinoma (primary ovarian) by [REDACTED]

2. FS2 RT.TUBE & OVARY

Adenocarcinoma (primary ovarian) by [REDACTED]

3. UTERUS

Gross examination only (no gross tumor seen) by [REDACTED]
called to [REDACTED]

GROSS DESCRIPTION:

1. FS1 LT.TUBE & OVARY

Received is large ovarian tumor with multilobular and nodular and cystic appearance weighing 783gm. and measuring 18x15x9cm. Cut sections show predominantly solid nodular component with creamy yellow soft parenchyma and thin walled cyst containing serous fluid with inner smooth lining surface measuring 9x6cm. in diameter. The nodules ranging from 0.5cm. to 8cm. in overall dimension in size and from yellow to deep purple in color. The fallopian tube is grossly not identified. Sections submitted as follows:

T1,T2: tumor with cyst wall

T3 to T8: representatives of the solid tumor

FT: fallopian tube

2. FS2 RT.TUBE & OVARY

Received fresh is a large ovarian mass demonstrating multinodular and multilobulated appearance with focal cystic changes and weighing 290gm. and measuring 13x8x5cm. Fallopian tube is also present measuring 5cm. in length and 0.5cm. in diameter. The color of the outer surface of the ovary ranges from yellow tan to pink purple. The size of the nodules range from 0.4cm. to 5cm. in overall dimension. Multiple small hemorrhagic cysts are identified. On serial sections, ovary reveals nodules having a solid consistency. Multiple yellow necrotic areas multiple cyst formation. There are focal thickening of the cyst wall. No normal ovary is identified. Sections submitted as follows:

FT: fallopian tube

T1 to T3: cystic components of the tumor

T4 to T8: solid components of the tumor

3. UTERUS

[page 3 of 4]
[REDACTED]

Received fresh is a uterus weighing 152gm. and measuring 12x7.4cm. The serosa is smooth and apparent subserosal fibroid seen located near the junction of cervix and lower segment of uterus and measures 0.8cm. in overall dimension. The uterus is opened along the lateral margin which reveals a hyperemic endometrium with velvety appearance. No definite gross tumor seen. The cervix is grossly unremarkable. Serial sectioning of the uterus and cervix reveal unremarkable endo and myometrium. No focal lesion identified. The endometrium measures 0.2cm. The myometrium measures 2cm. in thickness. Sections submitted as follows:

AEM: anterior endometrium
PEM: posterior endometrium
AC1,2: anterior cervix
PC1,2: posterior cervix
F: fibroid

4. LEFT PELVIC LYMPH NODES

Received in formalin are three fragments of fibroadipose tissue ranging from 1x1.8x0.7cm. to 3.2x2.3x1.4cm. Five lymph nodes identified ranging from 4x1x0.7cm. to 0.5x0.3x0.3cm. Lymph nodes submitted as follows:

LN1A,B: one lymph node
LN2: two bisected lymph nodes
LN3: two bisected lymph nodes

5. RT PELVIC LYMPH NODES

Received in formalin are two fragments of fibroadipose tissue measuring 2.3x1.1x0.7cm. and 3.1x1.7x1.1cm. Three lymph nodes are identified. Sections submitted as follows:

LN1: one bisected lymph node
LN2: two bisected lymph nodes

6. BX SIGMOID NODULE

Received in formalin is a fragment of tan soft tissue measuring 0.4x0.3x0.1cm. The specimen submitted in toto in cassette labelled SM.

7. PERI-AORTIC LYMPH NODES

Received in formalin are four fragments of tan pink focally hemorrhagic nodule ranging from 3.5x0.6x0.4cm. to 4.2x2.8x2.1cm. Serial sections of the nodules reveals a white yellowish tan lobulated cut surface with focal hemorrhage. Sections submitted as follows:

LN1,2: two largest nodes
LN3: one lymph node
LN4: one lymph node

8. OMENTUM

[REDACTED]

[page 4 of 4]
Received in formalin is a 30x8x1 cm. segment of omentum. Grossly, no tumor is seen on the surface. No lymph nodes are identified. Representatives are submitted in four cassettes labelled O1 to O4.

9. TUMOR SIGMOID MESENTERIC

Received in formalin is a tan white fragment of soft rubbery tissue measuring 0.3x0.2x0.2 cm. Submitted in toto in cassette labelled

10. OVARIAN TUMOR

Received fresh is a yellow soft nodule measuring 3x2x2.3 cm. Cut section shows lobulated yellow cut surface. Representative submitted in T. The rest of the specimen is sent to for further investigation.

Source: NCI Genomic Data Commons file beea6cbf-b7f6-43a6-a8f0-fe794d6b9a8c (TCGA-59-2351.6CEC74E9-4AD7-4C6D-ABDD-36BA1573D6AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).